Somatic mutation profile of tumor specimen TCGA-D5-6541-01A (aliquot TCGA-D5-6541-01A-11D-1719-10) from TCGA case TCGA-D5-6541, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.4 years (18,029 days).
Specimen TCGA-D5-6541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ef159e4-1b0a-42c4-8058-d5331fd34b3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6541-10A (Blood Derived Normal), aliquot TCGA-D5-6541-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e77178df-09d0-41c0-9307-5ce3d0104039

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 23, Nonsense Mutation 5, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.88_99del p.Y30_S33del | In Frame Del (DEL) | VAF 146/271 reads (54%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCBP1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 42/117 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 229/791 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 41/128 reads (32%) | catalogued as rs759085500, COSV100617298; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC008676.3 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.069); catalogued as COSV56638363; called by muse, mutect2, varscan2
- ACAN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs376202313; called by muse, mutect2, varscan2
- ADGRE2 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs143659792, COSV100215907; called by muse, mutect2
- AKAP12 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs769926929, COSV53570776; called by muse, mutect2, varscan2
- ANO1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs371196052; called by muse, mutect2, varscan2
- ATAD3A | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); catalogued as rs776584627, COSV59236628; called by muse, mutect2, varscan2
- ATP2B2 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1479653862, COSV59508900; called by muse, mutect2, varscan2
- BIRC6 | c.11977C>T p.R3993* | Nonsense Mutation (SNP) | VAF 70/281 reads (25%) | catalogued as COSV101134360; called by muse, mutect2, varscan2
- BRD1 | c.2609C>T p.A870V (on ENST00000216267 / NM_001349940.1; = p.A1001V on NM_001304808.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs764535212, COSV53462493; called by muse, mutect2, varscan2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2, varscan2
- CCDC141 | c.3845C>T p.T1282I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs748086006, COSV55384350; called by muse, mutect2, varscan2
- CEP250 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs773558951, COSV61175325; called by muse, mutect2, varscan2
- COL6A2 | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755352246, COSV52430624; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.3433C>A p.L1145M | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV54101090, COSV99617094; called by muse, mutect2, varscan2
- CYP11B1 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.154); catalogued as rs1478938813, COSV52826941; called by muse, mutect2, varscan2
- CYP7A1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201114135, COSV56964884; called by muse, mutect2, varscan2
- DDX47 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs557371913, COSV61912184; called by muse, mutect2, varscan2
- DYNC2H1 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745436653, COSV100519421; called by muse, mutect2, varscan2
- EXD3 | c.482C>A p.T161K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555383988, COSV59814656; called by muse, mutect2, varscan2
- FAM47A | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs772335767, COSV60495726, COSV99080509; called by muse, mutect2
- FAT4 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.992); catalogued as COSV101272493; called by muse, mutect2, varscan2
- FLT4 | c.3209G>T p.R1070L | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771345898, COSV56101309, COSV56123218; called by muse, mutect2
- GALNT3 | c.1486G>T p.V496L | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773423949, COSV67062662; called by muse, mutect2, varscan2
- GOLGB1 | c.144_146del p.E48del | In Frame Del (DEL) | VAF 42/150 reads (28%) | catalogued as rs1198125353; called by pindel, varscan2
- HIRA | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745364733, COSV54280946; called by muse, mutect2, varscan2
- HRH2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs778386458, COSV51576501; called by muse, mutect2, varscan2
- IK | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70258377; called by muse, mutect2, varscan2
- KCNT2 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 144/489 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54064372, COSV99657503; called by muse, mutect2, varscan2
- KLHL41 | c.690dup p.Y231Ifs*3 | Frame Shift Ins (INS) | VAF 32/94 reads (34%) | catalogued as rs1158239220; called by mutect2, pindel, varscan2
- MAG | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs756136921, COSV62698782; called by muse, mutect2, varscan2
- MAP4K4 | c.2426C>T p.T809M (on ENST00000347699 / NM_001242559.2; = p.T727M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs372783884; called by muse, mutect2, varscan2
- MYH13 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367783054; called by muse, mutect2, varscan2
- MYH6 | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs139265690; called by muse, mutect2, varscan2
- NKX2-2 | c.253T>G p.Y85D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV65819597, COSV65820496; called by muse, mutect2, varscan2
- NR0B1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66764947; called by muse, mutect2, varscan2
- NR1H3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68008971; called by muse, mutect2, varscan2
- NTRK2 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52886314; called by muse, mutect2, varscan2
- OR4D10 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 121/433 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs200781301; called by muse, mutect2, varscan2
- OR5AS1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 195/656 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100546429; called by muse, mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | catalogued as rs750155763; called by mutect2, pindel, varscan2
- PANX3 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs777601144, COSV52511591; called by muse, mutect2, varscan2
- PPP2R5E | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV61744773; called by muse, mutect2, varscan2
- PRMT1 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV67160575; called by muse, mutect2, varscan2
- RDH5 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as rs759835915, COSV57676810; called by muse, mutect2, varscan2
- RELN | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1252404801, COSV58995083; called by muse, mutect2, varscan2
- RIMS2 | c.4291C>T p.R1431C (on ENST00000666250 / NM_001348490.2; = p.R1002C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 235/464 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763285258, COSV51660936; called by muse, mutect2, varscan2
- RYR2 | c.12340C>T p.R4114* | Nonsense Mutation (SNP) | VAF 56/250 reads (22%) | catalogued as rs1430428297, COSV100773096; called by muse, mutect2, varscan2
- SCN8A | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs752265946, COSV61994238; called by muse, mutect2, varscan2
- SHANK1 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV53259224; called by muse, mutect2, varscan2
- SIRT4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546233791, COSV52540289, COSV52541732; called by muse, mutect2, varscan2
- SLC23A3 | c.1601G>A p.R534Q (on ENST00000409878 / NM_001144889.2; = p.R417Q on NM_144712.5) | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs769388431, COSV55409979; called by muse, mutect2, varscan2
- SLC25A5 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV58628780, COSV58630409; called by muse, mutect2, varscan2
- SLC2A14 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs778496220, COSV61586827; called by muse, mutect2, varscan2
- SMARCC2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 171/612 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV57225961; called by muse, mutect2, varscan2
- SNTG1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769991462, COSV52435349; called by muse, mutect2, varscan2
- SPART | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV62089154; called by muse, mutect2
- SPOPL | c.640C>G p.H214D | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54517033; called by muse, mutect2, varscan2
- SPTB | c.3950C>T p.A1317V | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768710888, COSV101072455, COSV67635713; called by muse, mutect2, varscan2
- SV2B | c.1755dup p.G586Wfs*4 | Frame Shift Ins (INS) | VAF 99/395 reads (25%) | catalogued as rs1567438858; called by mutect2, pindel, varscan2
- SVIL | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs201516624; called by muse, mutect2, varscan2
- SYTL1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140755424, COSV58874949; called by muse, mutect2, varscan2
- TAS1R3 | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100229939; called by muse, mutect2, varscan2
- TENT5D | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs768296665, COSV57639667; called by muse, mutect2, varscan2
- TGIF1 | c.192del p.W65Gfs*14 (on ENST00000330513 / NM_001374396.1; = p.W85Gfs*14 on NM_003244.4) | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as COSV57909859; called by mutect2, pindel, varscan2
- THSD7B | c.1416G>T p.L472F | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.21); catalogued as COSV99759456; called by muse, mutect2, varscan2
- TMEM132B | c.3071T>C p.V1024A | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100171280; called by muse, varscan2
- TP53TG5 | c.781T>C p.W261R | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs773867397, COSV99714030; called by muse, mutect2, varscan2
- VPS13B | c.5305C>T p.Q1769* | Nonsense Mutation (SNP) | VAF 31/176 reads (18%) | catalogued as COSV62160333; called by muse, mutect2, varscan2
- WDHD1 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV62216014; called by muse, mutect2, varscan2
- WHRN | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1413225135, COSV54333597; called by muse, mutect2, varscan2
- XKR7 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374398061; called by mutect2, varscan2
- COL4A5 | c.1266T>A p.P422= | Silent (SNP) | VAF 63/216 reads (29%) | catalogued as COSV100090534; called by muse, mutect2, varscan2
- CRB1 | c.1974C>A p.I658= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV66328480; called by muse, mutect2, varscan2
- CUBN | c.9165C>T p.Y3055= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as rs146539020; called by muse, mutect2, varscan2
- EBF1 | c.1449C>T p.S483= | Silent (SNP) | VAF 78/299 reads (26%) | catalogued as rs1231975468, COSV58188744; called by muse, mutect2, varscan2
- ELL | c.585C>T p.A195= | Silent (SNP) | VAF 154/251 reads (61%) | catalogued as rs772428991, COSV53216248; called by muse, mutect2, varscan2
- EZHIP | c.72C>T p.N24= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1557318573, COSV100539788; called by muse, mutect2, varscan2
- FOCAD | c.5124G>A p.P1708= | Silent (SNP) | VAF 63/205 reads (31%) | catalogued as rs370546418; called by muse, mutect2, varscan2
- FOXG1 | c.984C>T p.N328= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs774246700, COSV57396529; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR68 | c.742C>T p.L248= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53177645; called by muse, mutect2, varscan2
- H2AC14 | c.348G>A p.L116= | Silent (SNP) | VAF 231/401 reads (58%) | catalogued as rs201801053, COSV60797205; called by muse, mutect2, varscan2
- IRAK2 | c.1779G>A p.S593= | Silent (SNP) | VAF 52/177 reads (29%) | catalogued as rs372211228; called by muse, mutect2, varscan2
- KDM5A | c.4944T>A p.A1648= | Silent (SNP) | VAF 87/598 reads (15%) | catalogued as COSV66996845; called by muse, mutect2, varscan2
- KIF26B | c.3612C>T p.S1204= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs746673858, COSV63651868; called by muse, mutect2, varscan2
- KLHL34 | c.1095C>A p.G365= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV65280463; called by muse, mutect2, varscan2
- MPDZ | c.1713G>A p.A571= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs940890746, COSV59956216; called by muse, varscan2
- OBSCN | c.9099C>T p.Y3033= | Silent (SNP) | VAF 71/212 reads (33%) | catalogued as rs371187428; called by muse, mutect2, varscan2
- OR4E2 | c.357G>A p.A119= | Silent (SNP) | VAF 134/478 reads (28%) | catalogued as rs200065979, COSV57732130; called by muse, mutect2, varscan2
- PDCL2 | c.177T>C p.D59= | Silent (SNP) | VAF 52/198 reads (26%) | catalogued as COSV55263479; called by muse, varscan2
- PNPLA6 | c.876G>A p.T292= (on ENST00000414982 / NM_001166111.2; = p.T244= on NM_006702.5) | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as rs775074101, COSV99654679; called by muse, mutect2, varscan2
- PTPN9 | c.1584G>A p.L528= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV100144394, COSV60726368; called by muse, mutect2, varscan2
- UNC79 | c.4053T>C p.Y1351= (on ENST00000393151 / NM_001346218.2; = p.Y1174= on NM_020818.5) | Silent (SNP) | VAF 53/184 reads (29%) | catalogued as COSV56416273; called by muse, mutect2, varscan2
- USP53 | c.1518T>C p.H506= | Silent (SNP) | VAF 69/301 reads (23%) | catalogued as rs535438483, COSV56798334; called by muse, mutect2, varscan2
- WWC2 | c.2397C>T p.C799= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV66717425; called by muse, mutect2, varscan2
- STEAP3 | c.-77+7123G>A | Intron (SNP) | VAF 15/88 reads (17%) | catalogued as rs761921420, COSV100713384; called by muse, mutect2, varscan2
- UCHL5 | chr1:193059508 G>T | 5'Flank (SNP) | VAF 77/248 reads (31%) | catalogued as COSV100814696; called by muse, mutect2, varscan2
